MMRF case MMRF_2590 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4ff7bf7e-0993-4e3f-b722-caa928798afb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.1 years (26,340 days); ISS stage: III; Days to last known disease status: 527 days (1.4 years); Days to last follow up: 527 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 50 days; Days to treatment end: 60 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 71 days; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Bortezomib + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 120 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 192 days; Days to treatment end: 199 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 192 days; Days to treatment end: 253 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 199 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 17.7 mg/dL; Immunoglobulin G 23.2 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 7 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 8.1 g/dL; Glucose 9.52 mmol/L; C-Reactive Protein 0.26 mg/dL.
- Day 64 (ECOG 1): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.66 mg/dL; Immunoglobulin G 9.51 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 6.66 mmol/L.
- Day 169 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.71 mg/dL; Immunoglobulin G 6.68 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.44 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 277 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 49 g/L; Total Protein 8 g/dL; Glucose 9.08 mmol/L.
- Day 253 (ECOG 1): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.32 mg/dL; Immunoglobulin G 6.31 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 5.6 g/dL; Glucose 9.79 mmol/L.
- Day 344 (ECOG 1): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.11 mg/dL; Immunoglobulin G 7.49 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 4.18 mmol/L.
- Day 413 (ECOG 1): M Protein 0.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.95 mg/dL; Immunoglobulin G 7.37 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 9.52 mmol/L.
- Day 527 (ECOG 1): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.93 mg/dL; Immunoglobulin G 7.25 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 11 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 3.36 mmol/L.

Other clinical attributes
- Day -13: Weight: 85 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2590_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_2590_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
